Gene-level copy-number profile of tumor specimen ALCH-AEKC-TTP1-A from ALCHEMIST case ALCH-AEKC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.1 years (27,065 days).
Specimen ALCH-AEKC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 195864ab-418d-4fb2-b932-7558f0ea49ac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEKC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,751 have no estimate.
https://portal.gdc.cancer.gov/files/c0c20e8b-71e6-404b-9e8f-04fa88e374dc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 612; copy number 1: 17,124; copy number 2: 28,820; copy number 3: 8,030; copy number 4: 3,153; copy number 5: 706; copy number 6: 72; copy number 7: 89; copy number 8: 52; copy number 9: 4; copy number 10: 99; copy number 14: 50; copy number 16: 21; copy number 19: 39; copy number 29: 1.

Homozygous deletions (total copy number 0; autosomes only): 100 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,551–91,105, 1 gene (within-gene range 0–1): AL627309.3.
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr1:143,929,994–143,930,382, 1 gene (within-gene range 0–1): RPL22P5.
- chr1:144,085,628–144,373,659, 8 genes: IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr4:25,472,517–25,929,874, 16 genes: AC133963.2, AC133963.1, AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1.
- chr7:45,789,585–45,789,688, 1 gene: RNU6-241P.
- chr8:30,349,866–30,353,518, 2 genes: PPIAP84, TUBBP1.
- chr8:55,893,595–55,902,855, 2 genes (within-gene range 0–1): AC018607.1, SNORA1B.
- chr9:21,231,266–23,956,444, 52 genes: IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3.
- chr9:114,611,206–114,662,374, 3 genes: TMEM268, Y_RNA, TEX53.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr17:17,616,043–17,677,688, 4 genes: AC020558.5, SMCR2, AC020558.3, AC020558.4.
- chr18:45,034–94,330, 5 genes: AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2.
- chr18:21,182,503–21,183,499, 1 gene: EXOGP1.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,133 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:55,865,967–72,148,038, 296 genes, copy number 5–7 (broad region; genes not listed).
- chr3:164,001,606–172,401,669, 115 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:176,415,439–185,980,872, 193 genes, copy number 5–29 (broad region; genes not listed).
- chr5:135,802,985–135,803,075, 1 gene, copy number 5: MIR5692C1.
- chr6:4,610,612–4,611,919, 1 gene, copy number 5: KU-MEL-3.
- chr9:127,397,138–127,724,873, 12 genes, copy number 5 (within-gene range 2–5): SLC2A8, ZNF79, RPL12, SNORA65, LRSAM1, Y_RNA, NIBAN2, STXBP1, AL162426.1, PTRH1, MIR3911, CFAP157.
- chr12:69,284,397–71,441,898, 37 genes, copy number 5–8 (within-gene range 2–8): C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8.
- chr15:25,333,728–25,439,051, 2 genes, copy number 6 (within-gene range 4–6): UBE3A, AC100774.1.
- chr15:40,258,501–40,755,851, 31 genes, copy number 7 (within-gene range 2–7): AC020658.6, PLCB2, ANKRD63, AC020658.5, PLCB2-AS1, AC020658.1, AC020658.2, INAFM2, CCDC9B, RNA5SP392, PHGR1, DISP2, AC013356.4, KNSTRN, IVD, BAHD1, AC013356.3, AC013356.2, CHST14, AC013356.1, AC091045.1, CCDC32, RNU6-516P, RPUSD2, Metazoa_SRP, KNL1, RN7SL376P, AC022405.1, RAD51-AS1, RAD51, RMDN3.
- chr15:42,575,606–42,720,998, 1 gene, copy number 6 (within-gene range 2–6): STARD9.
- chr15:42,723,544–43,668,118, 39 genes, copy number 6 (within-gene range 2–6): CDAN1, AC090510.3, AC090510.2, TTBK2, AC090510.1, AC090510.4, KRT8P50, FDPSP4, UBR1, AC068724.3, AC068724.2, RPS3AP47, TMEM62, SPCS2P1, AC068724.4, AC068724.1, CCNDBP1, EPB42, TGM5, Y_RNA, ATP5PDP1, TGM7, AC009852.1, LCMT2, ADAL, ZSCAN29, TUBGCP4, RN7SL487P, TP53BP1, MAP1A, PPIP5K1, CKMT1B, STRC, RNU6-554P, AC011330.3, CATSPER2, RNU6-610P, AC011330.2, PDIA3P2.
- chr15:51,751,597–57,782,762, 109 genes, copy number 5–10 (broad region; genes not listed).
- chr15:58,138,169–58,185,911, 6 genes, copy number 8 (within-gene range 2–8): AQP9, MTCO3P23, MTND3P12, AC066616.2, MTND5P32, MTCYBP23.
- chr15:66,488,658–67,065,268, 20 genes, copy number 8 (within-gene range 2–8): AC116913.1, SNAPC5, MIR4512, RPL4, SNORD18C, AC116913.2, SNORD18B, SNORD16, SNORD18A, ZWILCH, LCTL, LINC01169, SMAD6, AC013564.1, AC110048.1, AC110048.2, AC093334.1, LINC02206, AC087482.1, HMGN2P47.
- chr15:72,159,806–72,798,199, 29 genes, copy number 6: GRAMD2A, PKM, PARP6, AC009690.3, AC009690.2, CELF6, AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1.
- chr15:93,718,542–94,600,821, 14 genes, copy number 7 (within-gene range 2–7): LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581, AC104390.1, H3P40, MCTP2, AC135626.1, AC135626.2, AC009432.2, AC009432.1.
- chr16:33,988,406–33,991,551, 1 gene, copy number 5: BCAP31P1.
- chr16:34,978,744–35,085,060, 6 genes, copy number 6–19 (within-gene range 4–19): LINC02184, AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.
- chr17:48,607,232–48,647,023, 6 genes, copy number 5 (within-gene range 3–5): HOXB7, HOXB8, HOXB9, HOXB-AS4, MIR196A1, AC103702.2.
- chr18:31,318,160–32,938,316, 47 genes, copy number 5 (within-gene range 2–5): DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2.
- chr19:36,817,428–37,614,179, 31 genes, copy number 5 (within-gene range 3–5): ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571.
- chr19:37,667,751–40,299,584, 136 genes, copy number 8–19 (within-gene range 3–19) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,804. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
